Somatic mutation profile of tumor specimen MP2PRT-PAUEYI-TMP1-A (aliquot MP2PRT-PAUEYI-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUEYI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (986 days).
Specimen MP2PRT-PAUEYI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b78e70aa-f987-4a48-a7f9-c1d48d6f7e69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEYI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEYI-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53fb1d07-707f-4b71-9ab6-0e46e7f2d451

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 78/342 reads (23%) | catalogued as rs781223647, CM001804, COSV100240460, COSV56332304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs547641233, COSV62005182, COSV62012587; called by mutect2, varscan2
- SYBU | c.65G>A p.R22Q (on ENST00000276646 / NM_001099754.2; = p.R21Q on NM_017786.6) | Missense Mutation (SNP) | VAF 56/636 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1405679757, COSV99406206; called by muse, mutect2
- ARHGAP31 | c.1588T>C p.S530P | Missense Mutation (SNP) | VAF 101/422 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDR2L | c.975C>T p.I325= | Silent (SNP) | VAF 108/944 reads (11%) | catalogued as rs1256405357; called by muse, mutect2, varscan2
- SYT3 | c.1530C>T p.S510= | Silent (SNP) | VAF 20/604 reads (3%) | catalogued as rs1046985127; called by muse, mutect2
